Somatic mutation profile of tumor specimen TARGET-40-PAMEKS-01A (aliquot TARGET-40-PAMEKS-01A-01D) from TARGET case TARGET-40-PAMEKS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.8 years (3,942 days).
Specimen TARGET-40-PAMEKS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc76e070-3fa3-40fc-a4b8-88d1000ecc9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMEKS-10A (Blood Derived Normal), aliquot TARGET-40-PAMEKS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2196c9b-9fbe-475e-b382-278436625bee

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 2, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs4635033, COSV55064748; called by mutect2, varscan2
- CFAP45 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV63650302; called by muse, mutect2
- EIF2AK3 | c.1764-1G>A p.X588_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100304048; called by muse, mutect2, varscan2
- KCNH1 | c.1886T>G p.I629S (on ENST00000271751 / NM_172362.3; = p.I602S on NM_002238.4) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99056061; called by muse, mutect2, varscan2
- PKP2 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50744295; called by muse, mutect2, varscan2
- VARS2 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 157/322 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140305500; called by muse, mutect2, varscan2
- CNTNAP5 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.474); called by mutect2, varscan2
- CYFIP2 | c.2812T>G p.F938V (on ENST00000616178 / NM_001291722.2; = p.F913V on NM_014376.4) | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, varscan2
- DCAF11 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP5-11 | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NEB | c.646del p.S216Vfs*12 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- OR4M1 | c.482C>G p.A161G | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SENP8 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP5L | c.2932T>C p.S978P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF605 | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF91 | c.2533A>C p.K845Q | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRINP3 | c.1341T>A p.S447= | Silent (SNP) | VAF 36/46 reads (78%) | called by muse, mutect2, varscan2
- CEP131 | c.1059G>A p.K353= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MYO6 | c.462A>T p.G154= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- NEUROD4 | c.903T>A p.G301= | Silent (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
- CBY1 | c.79-79A>C | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2
- RPL35 | c.140+17G>T | Intron (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.-52G>A | 5'UTR (SNP) | VAF 41/64 reads (64%) | called by muse, mutect2, varscan2
